Somatic mutation profile of tumor specimen 0DIPKY from CCDI case PBBVVV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 9.7 years (3,549 days).
Specimen 0DIPKY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a653ecf-0a05-4e69-9405-aedd58216707.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa08719f-8bbd-4c79-9d0c-68a1c8140818

The open-access MAF lists 12 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 4, Silent 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.5480C>T p.P1827L | Missense Mutation (SNP) | VAF 82/1712 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs778780920, COSV56359549; called by muse, mutect2
- ANKRD30B | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 123/1163 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs759293133; called by muse, mutect2, varscan2
- HNF1A | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 70/341 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as CM013294; called by muse, mutect2, varscan2
- QARS1 | c.248C>T p.T83I | Missense Mutation (SNP) | VAF 156/822 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 19/362 reads (5%) | catalogued as rs1167537044; called by muse, mutect2
- MEFV | c.819G>A p.S273= | Silent (SNP) | VAF 81/592 reads (14%) | catalogued as rs962267537, COSV54819966, COSV99560305; ClinVar: likely benign; called by muse, mutect2, varscan2
- OLFM3 | c.1062C>T p.I354= (on ENST00000338858 / NM_001288821.1; = p.I334= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 210/1090 reads (19%) | catalogued as rs752339884; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 21/135 reads (16%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 21/132 reads (16%) | called by muse, varscan2
- NCBP3 | c.797-99G>A | Intron (SNP) | VAF 9/46 reads (20%) | catalogued as rs1248488199; called by muse, mutect2, varscan2
- RMI1 | c.-10T>A | 5'UTR (SNP) | VAF 26/324 reads (8%) | called by mutect2, varscan2
- TENM3 | c.5068+96G>A | Intron (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
